Somatic mutation profile of tumor specimen C3L-04508-54 (aliquot CPT0260410002) from CPTAC case C3L-04508, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 60.6 years (22,148 days).
Specimen C3L-04508-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c117d05-7fa9-4071-9a6c-1ba918d6cb13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04508-51 (Buccal Cell Normal), aliquot CPT0260400003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3e296a5-2370-419c-a8fd-52525a643e60

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 20/344 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- MID1 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs370465458; called by muse, mutect2, varscan2
- NOVA2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs989602487; called by muse, mutect2, varscan2
- OR6B1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 25/212 reads (12%) | catalogued as rs745433880, COSV68770009; called by muse, varscan2
- RPL10A | c.6-9C>A | Intron (SNP) | VAF 44/283 reads (16%) | called by muse, varscan2
